Somatic mutation profile of tumor specimen MP2PRT-PANMVY-TMP1-A (aliquot MP2PRT-PANMVY-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANMVY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,119 days).
Specimen MP2PRT-PANMVY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50f1cb48-0638-41d0-867f-0666358d1dc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANMVY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANMVY-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1693ed12-cc49-41d4-90ff-490028b09ad3

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 73/443 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ATP6V0D2 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs370400701, COSV99035293; called by muse, mutect2
- BEST2 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 30/758 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV50358569; called by muse, mutect2
- RNF111 | c.2191A>G p.I731V | Missense Mutation (SNP) | VAF 188/384 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs1454581847; called by muse, mutect2, varscan2
- ZNF318 | c.1430A>C p.K477T | Missense Mutation (SNP) | VAF 205/528 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100546403; called by muse, mutect2, varscan2
- ADAM7 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 185/431 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ATP8A2 | c.2758T>C p.F920L | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BDP1 | c.1005A>G p.I335M | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- TFG | c.821-1G>A p.X274_splice | Splice Site (SNP) | VAF 162/324 reads (50%) | called by muse, mutect2, varscan2
- ASB4 | c.891C>T p.S297= | Silent (SNP) | VAF 29/578 reads (5%) | catalogued as rs536909102; called by muse, mutect2
- GLYATL2 | c.264C>G p.V88= | Silent (SNP) | VAF 117/241 reads (49%) | called by muse, mutect2, varscan2
- GPR149 | c.588C>T p.I196= | Silent (SNP) | VAF 32/748 reads (4%) | catalogued as rs1358765958, COSV67669476; called by muse, mutect2
- IGHV3-53 | c.349_350insTCGGCCCTAGGAG p.*117delinsVGPRR | Silent (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel*
- SALL1 | c.2676C>A p.S892= | Silent (SNP) | VAF 168/570 reads (29%) | catalogued as COSV51759261; called by muse, mutect2, varscan2
